Gene-level copy-number profile of tumor specimen TCGA-GC-A3WC-01A from TCGA case TCGA-GC-A3WC, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 80.2 years (29,295 days).
Specimen TCGA-GC-A3WC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.9ed0a0d2-9670-4b72-826c-ef9ba0674e6e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GC-A3WC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fef1a362-306b-41fb-b8a2-19e580f281a8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 6,553; copy number 2: 43,863; copy number 3: 7,973; copy number 4: 1,367; copy number 5: 55.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GC-A3WC-01A-31D-A22Y-01): tumor purity 0.38, ploidy 2.04, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:3,700,492–3,700,628, 1 gene: RNA5SP251.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 55 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:65,669,961–66,329,377, 9 genes, copy number 5: EPHA5-AS1, AC104137.1, RNU2-40P, AC097110.1, AC116049.1, AC096721.1, IFITM3P1, AC110809.1, MIR1269A.
- chr21:35,887,195–37,203,112, 46 genes, copy number 5: PPP1R2P2, LINC01436, RPL23AP3, SETD4, RIMKLBP1, SETD4-AS1, RNU6-992P, AP000688.1, CBR1, AP000688.3, AP000688.2, MEMO1P1, CBR3-AS1, RPS9P1, CBR3, DOP1B, RPL3P1, SRSF9P1, AP000692.2, MORC3, AP000692.1, CHAF1B, ATP5MFP1, AP000695.1, AP000695.2, CLDN14, AP000695.3, PSMD4P1, AP000696.2, AP000696.3, AP000696.1, AP000697.1, SIM2, HLCS, HLCS-IT1, RNA5SP491, DPRXP5, AP000704.1, Y_RNA, MRPL20P1, RIPPLY3, RNU6-696P, PIGP, TTC3, AP001429.1, TTC3-AS1.

Autosomal genes at a single copy (total copy number 1): 6,553. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
